Somatic mutation profile of tumor specimen 0DVR8F from CCDI case PBCNCY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Renal pelvis; Age at diagnosis: 2.6 years (935 days).
Specimen 0DVR8F: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8054f333-f7f3-4204-839e-4a6a7a04d8f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19260ae2-b997-4c3d-8b72-fcb2226fdfd9

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND4C | c.4981G>A p.A1661T (on ENST00000434457 / NM_001330640.2; = p.A1612T on NM_017925.7) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs138927614; called by muse, mutect2, varscan2
- PGM2L1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 15/362 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99994830; called by muse, mutect2
- ULK3 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV71348044; called by muse, mutect2
- BCORL1 | c.3125G>T p.S1042I | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.562); called by muse, mutect2
- COL4A6 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- PKN3 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ZNF534 | c.1483C>T p.Q495* (on ENST00000332323 / NM_001143939.3; = p.Q482* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
- CCDC25 | c.513A>G p.K171= | Silent (SNP) | VAF 33/284 reads (12%) | called by muse, varscan2
- LAMB2 | c.4574-33C>A | Intron (SNP) | VAF 18/107 reads (17%) | called by muse, varscan2
- MAB21L4 | c.515-128C>A | Intron (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- WFDC2 | c.224-57A>T | Intron (SNP) | VAF 16/42 reads (38%) | called by mutect2, varscan2
